Somatic mutation profile of tumor specimen b75e68fd-cfa1-4e9e-b4c1-a57ad8 (aliquot b75e68fd-cfa1-4e9e-b4c1-a57ad8_D6) from CPTAC case 24CO005, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage III.
Specimen b75e68fd-cfa1-4e9e-b4c1-a57ad8: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79574a0e-71d3-4317-8c7b-a7c7cf7d334a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 3888c00c-99c7-44da-9234-5959f8 (Blood Derived Normal), aliquot 3888c00c-99c7-44da-9234-5959f8_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c80bcbb0-a8d8-491b-9191-5d50e1e905df

The open-access MAF lists 75 somatic variants for this specimen: 42 protein-altering or splice-affecting, 20 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 20, Intron 3, 5'UTR 3, Nonsense Mutation 3, 3'UTR 2, RNA 2, 3'Flank 2, Frame Shift Del 2, Frame Shift Ins 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 100/312 reads (32%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.653T>A p.V218E | Missense Mutation (SNP) | VAF 214/484 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52690974, COSV52712839, COSV52761003; called by muse, mutect2, varscan2
- ADAMTS18 | c.2447G>A p.G816E | Missense Mutation (SNP) | VAF 48/324 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV51411130, COSV51424470; called by muse, mutect2, varscan2
- AGBL2 | c.1474A>G p.I492V | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV54093910; called by muse, mutect2, varscan2
- AP000812.4 | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 16/120 reads (13%) | catalogued as rs1396507334; called by muse, mutect2, varscan2
- CD8B | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 122/382 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.913); catalogued as rs755618216; called by muse, mutect2, varscan2
- CSMD2 | c.2863G>A p.E955K | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs757085822, COSV53891958; called by muse, mutect2, varscan2
- CTNND2 | c.2249C>T p.A750V | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs750856111; called by muse, mutect2, varscan2
- CUL4B | c.2686C>T p.R896W | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1257568293; called by muse, mutect2, varscan2
- FAM187B | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 147/684 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.236); catalogued as rs149083793; called by muse, mutect2, varscan2
- FBN3 | c.3118G>A p.G1040S | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs751149718; called by muse, mutect2, varscan2
- GRM6 | c.2192G>A p.R731Q | Missense Mutation (SNP) | VAF 133/459 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs142842560; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HADH | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs1466918215; called by muse, mutect2
- KIAA1755 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs759318204; called by muse, mutect2, varscan2
- LCT | c.4126C>T p.R1376W | Missense Mutation (SNP) | VAF 190/703 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as rs1239488063, COSV99930518; called by muse, mutect2, varscan2
- LRP2 | c.1330G>A p.V444M | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as rs148503556; called by muse, mutect2, varscan2
- MOBP | c.215G>A p.R72H (on ENST00000420739; = p.R96H on NM_001278322.2) | Missense Mutation (SNP) | VAF 52/202 reads (26%) | PolyPhen probably damaging (0.991); catalogued as rs763986350; called by muse, mutect2, varscan2
- NNT | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs775681133, COSV52926931; called by muse, mutect2, varscan2
- NPTX2 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.999); catalogued as rs936955349, COSV55718362; called by muse, mutect2, varscan2
- PDZRN4 | c.2879G>A p.R960H (on ENST00000402685 / NM_001164595.2; = p.R702H on NM_013377.4) | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748727154, COSV54216779; called by muse, mutect2, varscan2
- SPTBN5 | c.5500C>T p.R1834* | Nonsense Mutation (SNP) | VAF 47/320 reads (15%) | catalogued as rs377166485; called by muse, varscan2
- TCF21 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 107/498 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52818115; called by muse, mutect2, varscan2
- THEMIS2 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375363209; called by muse, mutect2, varscan2
- UROC1 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 170/668 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.159); catalogued as rs527715107; called by muse, mutect2, varscan2
- ZFP64 | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1431389336; called by muse, mutect2, varscan2
- ARMH1 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 65/277 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- C12orf56 | c.335dup p.L112Ffs*6 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by pindel, varscan2
- CCDC158 | c.2221G>A p.G741S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLDN5 | c.185T>C p.M62T (on ENST00000618236 / NM_001363066.2; = p.M147T on NM_003277.4) | Missense Mutation (SNP) | VAF 30/476 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2
- COPB1 | c.1747G>C p.A583P | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- DDN | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- DNAH11 | c.12091C>T p.H4031Y | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- DOCK11 | c.196A>G p.M66V | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GAS2 | c.107T>A p.M36K | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- GTF3C1 | c.3721dup p.S1241Kfs*8 | Frame Shift Ins (INS) | VAF 14/90 reads (16%) | called by mutect2, pindel, varscan2
- HMGCR | c.491del p.L164* | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | called by mutect2, pindel, varscan2
- HSPA4L | c.2093_2094del p.R698Tfs*6 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by pindel, varscan2
- IL22 | c.236T>G p.L79R | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNT2 | c.2857G>A p.D953N | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- PRICKLE2 | c.1519A>G p.R507G (on ENST00000295902; = p.R451G on NM_198859.4) | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- ZHX2 | c.1177A>G p.I393V | Missense Mutation (SNP) | VAF 51/346 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF792 | c.905A>G p.K302R | Missense Mutation (SNP) | VAF 129/536 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS20 | c.4026C>T p.C1342= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as rs148216689; called by muse, mutect2, varscan2
- ADCY6 | c.1662C>T p.G554= | Silent (SNP) | VAF 49/524 reads (9%) | catalogued as rs776107191, COSV57166760; called by muse, mutect2
- ADGRL4 | c.2025T>C p.Y675= | Silent (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- CDC42EP1 | c.1008G>A p.A336= | Silent (SNP) | VAF 23/121 reads (19%) | catalogued as rs368461789; called by muse, mutect2, varscan2
- CFTR | c.2835G>A p.S945= | Silent (SNP) | VAF 142/577 reads (25%) | catalogued as rs193922513, COSV50081176; ClinVar: uncertain significance / benign / likely benign; called by muse, mutect2, varscan2
- DOCK1 | c.4827G>A p.E1609= | Silent (SNP) | VAF 34/175 reads (19%) | called by muse, mutect2, varscan2
- EEF1A2 | c.384C>A p.S128= | Silent (SNP) | VAF 77/556 reads (14%) | called by muse, mutect2, varscan2
- EMSY | c.3510C>G p.P1170= | Silent (SNP) | VAF 32/184 reads (17%) | called by muse, mutect2, varscan2
- FAM120A | c.1632C>T p.T544= | Silent (SNP) | VAF 42/261 reads (16%) | catalogued as COSV99466653; called by muse, mutect2, varscan2
- HEPN1 | c.42C>T p.G14= | Silent (SNP) | VAF 38/267 reads (14%) | catalogued as rs368280630, COSV53432572; called by muse, mutect2, varscan2
- LRP1B | c.3150T>G p.P1050= | Silent (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- LTBP3 | c.309C>T p.L103= | Silent (SNP) | VAF 44/194 reads (23%) | called by muse, mutect2, varscan2
- NUAK2 | c.1752C>T p.P584= | Silent (SNP) | VAF 142/377 reads (38%) | catalogued as COSV65682249; called by muse, mutect2, varscan2
- NUTM1 | c.1693C>T p.L565= | Silent (SNP) | VAF 31/260 reads (12%) | called by muse, mutect2, varscan2
- OR12D3 | c.543G>A p.P181= | Silent (SNP) | VAF 89/290 reads (31%) | catalogued as rs140727609; called by muse, mutect2, varscan2
- PPWD1 | c.714A>G p.V238= | Silent (SNP) | VAF 72/235 reads (31%) | catalogued as rs1428280977; called by muse, mutect2, varscan2
- RNF126 | c.711G>A p.A237= | Silent (SNP) | VAF 204/448 reads (46%) | catalogued as rs779853295; called by muse, varscan2
- SEMA3B | c.1116C>G p.V372= | Silent (SNP) | VAF 39/194 reads (20%) | called by muse, mutect2, varscan2
- SUGCT | c.63C>A p.G21= | Silent (SNP) | VAF 5/91 reads (5%) | called by muse, mutect2
- TRPV5 | c.981G>A p.P327= | Silent (SNP) | VAF 43/469 reads (9%) | catalogued as rs760393955, COSV54687769, COSV99520825; called by muse, mutect2
- AL353804.6 | n.68G>A | RNA (SNP) | VAF 24/165 reads (15%) | called by muse, mutect2, varscan2
- C1orf122 | c.*118T>G | 3'UTR (SNP) | VAF 27/165 reads (16%) | called by muse, mutect2, varscan2
- CCDC179 | c.-3G>A | 5'UTR (SNP) | VAF 20/207 reads (10%) | catalogued as rs982585096; called by muse, mutect2
- FABP5P3 | chr7:152445511 C>T | 3'Flank (SNP) | VAF 97/228 reads (43%) | called by muse, mutect2, varscan2
- JAKMIP1 | chr4:6049843 del T | 3'Flank (DEL) | VAF 12/115 reads (10%) | called by mutect2, pindel, varscan2
- MYADML | n.844G>A | RNA (SNP) | VAF 86/356 reads (24%) | called by muse, mutect2, varscan2
- NIPAL2 | c.*14A>G | 3'UTR (SNP) | VAF 25/131 reads (19%) | catalogued as COSV100358406; called by muse, mutect2, varscan2
- PNCK | c.69-85G>T | Intron (SNP) | VAF 95/308 reads (31%) | called by mutect2, varscan2
- PPM1K | c.542-2275G>T | Intron (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- SNED1 | c.3817+219_3817+220del | Intron (DEL) | VAF 56/203 reads (28%) | called by mutect2, pindel, varscan2
- TP63 | c.-26G>A | 5'UTR (SNP) | VAF 47/250 reads (19%) | catalogued as rs748630569, COSV53210863; called by muse, mutect2, varscan2
- USP17L30 | chr4:9359395 A>C | 5'Flank (SNP) | VAF 4/691 reads (1%) | called by muse, mutect2
- ZNF716 | c.-9C>T | 5'UTR (SNP) | VAF 41/159 reads (26%) | catalogued as rs782340963, COSV70780074; called by muse, mutect2, varscan2
